Somatic mutation profile of tumor specimen ALCH-B2FR-TTP1-A (aliquot ALCH-B2FR-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2FR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.3 years (19,843 days).
Specimen ALCH-B2FR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 529891a8-905d-421f-95cb-3e42d88ea11b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2FR-NB1-A (Blood Derived Normal), aliquot ALCH-B2FR-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/886cf78b-e4de-42a6-9a8b-34a7c93affc5

The open-access MAF lists 437 somatic variants for this specimen: 296 protein-altering or splice-affecting, 99 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 261, Silent 99, Nonsense Mutation 25, Intron 17, RNA 9, 3'UTR 7, 5'Flank 5, Splice Site 4, Frame Shift Del 4, 5'UTR 3, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 42/474 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 115/847 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AGAP6 | c.1610G>T p.R537M (on ENST00000374056 / NM_001365867.1; = p.R560M on NM_001077665.2) | Missense Mutation (SNP) | VAF 87/1256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782239986; called by muse, mutect2
- ANKRD34C | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs750628624, COSV101409601; called by muse, mutect2, varscan2
- ARFGEF3 | c.3298C>T p.R1100C | Missense Mutation (SNP) | VAF 27/178 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1483636261; called by muse, mutect2, varscan2
- BPNT2 | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.093); catalogued as COSV99075283; called by muse, mutect2, varscan2
- CACNA1I | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60802704; called by muse, mutect2
- CADM2 | c.1061G>T p.R354I (on ENST00000407528 / NM_001167674.2; = p.R356I on NM_153184.4) | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV67390007; called by muse, mutect2
- COL11A1 | c.5009G>A p.S1670N | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.134); catalogued as COSV62178053; called by muse, mutect2
- COL22A1 | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 41/298 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV100277314; called by muse, mutect2, varscan2
- COMMD8 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145737909; called by muse, mutect2, varscan2
- CPSF4L | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 40/425 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV61338268; called by muse, mutect2
- CSMD3 | c.10645G>T p.E3549* (on ENST00000297405 / NM_001363185.1; = p.E3380* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 73/482 reads (15%) | catalogued as COSV52101612, COSV52145848; called by muse, mutect2, varscan2
- CSPG4 | c.3226C>G p.R1076G | Missense Mutation (SNP) | VAF 40/397 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV57897043; called by muse, mutect2, varscan2
- CYP11B1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 58/726 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.21); catalogued as rs1170279039, COSV52826709; called by muse, mutect2
- DBF4 | c.1751G>T p.R584L | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99719292; called by muse, mutect2, varscan2
- DLX5 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 65/1115 reads (6%) | catalogued as COSV56033490; called by muse, mutect2
- DOCK10 | c.4371G>T p.Q1457H | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV51433484; called by muse, mutect2, varscan2
- DPYS | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 40/747 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as COSV60912902; called by muse, mutect2
- DTNA | c.869C>G p.T290R | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51999595, COSV52010650; called by muse, mutect2
- EML5 | c.3247G>A p.D1083N | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV100715957; called by muse, mutect2
- ERMARD | c.1521-1G>T p.X507_splice | Splice Site (SNP) | VAF 44/470 reads (9%) | catalogued as rs1205895812, COSV100824531; called by muse, mutect2
- EYS | c.1412A>G p.D471G | Missense Mutation (SNP) | VAF 25/296 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100676965; called by muse, mutect2
- F5 | c.2575A>T p.S859C | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as CD067863, COSV63126277; called by muse, mutect2
- FAM47A | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.361); catalogued as COSV60495353, COSV60496508; called by muse, mutect2
- FASTKD5 | c.1595G>T p.R532L | Missense Mutation (SNP) | VAF 37/399 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV53909887; called by muse, mutect2
- FLG | c.848C>G p.P283R | Missense Mutation (SNP) | VAF 72/1407 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs1370232933, COSV64242491; called by muse, mutect2
- G6PD | c.645-7C>A | Splice Region (SNP) | VAF 12/177 reads (7%) | catalogued as COSV63702230; called by muse, mutect2
- GAD2 | c.1426G>T p.E476* | Nonsense Mutation (SNP) | VAF 15/384 reads (4%) | catalogued as COSV52170951; called by muse, mutect2
- GLRA4 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV101009563; called by muse, mutect2
- GLT8D2 | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 54/375 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100673964, COSV62562404; called by muse, mutect2, varscan2
- GRIN2B | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 68/476 reads (14%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.955); catalogued as rs748075089, COSV101663194, COSV74205288; called by muse, mutect2, varscan2
- H3C11 | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 38/307 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs751578458, COSV58900725; called by muse, mutect2, varscan2
- HTR5A | c.158C>G p.A53G | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55283469; called by muse, mutect2
- IGHV3-64 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 22/499 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as rs1555567380; called by muse, mutect2
- IL18RAP | c.1783C>A p.Q595K | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.382); catalogued as COSV51825609; called by muse, varscan2
- ITGAM | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 17/248 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as COSV54936169; called by muse, mutect2
- KANK2 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV62009372; called by muse, mutect2, varscan2
- KHK | c.565G>T p.V189L | Missense Mutation (SNP) | VAF 22/654 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as rs879019463; called by muse, mutect2
- KRTAP6-3 | c.272T>A p.F91Y | Missense Mutation (SNP) | VAF 30/414 reads (7%) | PolyPhen benign (0.062); catalogued as rs1037016015; called by muse, mutect2
- LDB1 | c.1051G>T p.E351* (on ENST00000425280 / NM_001321612.2; = p.E317* on NM_003893.5) | Nonsense Mutation (SNP) | VAF 39/401 reads (10%) | catalogued as COSV100756314, COSV100756325; called by muse, mutect2
- LDLRAD4 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 119/574 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63336595; called by muse, mutect2, varscan2
- LHX8 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 44/689 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV53957497, COSV53958006; called by muse, mutect2
- LSAMP | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 47/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754613210; called by muse, mutect2, varscan2
- MAGEL2 | c.1783C>A p.P595T | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious, low confidence (0); catalogued as COSV58568147; called by muse, mutect2
- MEFV | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 61/762 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775224100, COSV54821492; called by muse, mutect2
- MMP21 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64288994; called by muse, mutect2
- MOB3C | c.119C>A p.S40* | Nonsense Mutation (SNP) | VAF 20/275 reads (7%) | catalogued as COSV54718272; called by muse, mutect2
- MXRA5 | c.6490C>T p.L2164F | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99479761; called by muse, mutect2
- MYMK | c.201G>T p.E67D | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs773689264; called by muse, mutect2
- MYO10 | c.4151G>T p.G1384V | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758869576; called by muse, mutect2
- NEUROD1 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 69/762 reads (9%) | catalogued as CM013586, COSV54548136; called by muse, mutect2
- NUP155 | c.4093C>T p.Q1365* (on ENST00000231498 / NM_153485.3; = p.Q1306* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 14/510 reads (3%) | catalogued as rs1209732982; called by muse, mutect2
- OR11G2 | c.467T>A p.M156K | Missense Mutation (SNP) | VAF 46/599 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1438347898; called by muse, mutect2
- OR1J1 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 51/415 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.248); catalogued as rs750331471; called by muse, mutect2, varscan2
- OR2M2 | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 49/696 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as COSV100677356, COSV62897910; called by muse, mutect2
- OR2T1 | c.668C>A p.T223K | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100822334; called by muse, mutect2, varscan2
- OR2T8 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 29/335 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.1); catalogued as COSV100178373; called by muse, mutect2, varscan2
- OR4C11 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV56352596; called by muse, mutect2, varscan2
- OR4K2 | c.321C>G p.F107L | Missense Mutation (SNP) | VAF 21/483 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV53851135; called by muse, mutect2
- OR5L2 | c.754C>A p.H252N | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV65725095; called by muse, varscan2
- OR5P3 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 47/391 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60429047; called by muse, mutect2, varscan2
- OTUD6A | c.736G>T p.G246W | Missense Mutation (SNP) | VAF 19/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57973736; called by muse, mutect2
- PABPC5 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 32/802 reads (4%) | SIFT tolerated (1); PolyPhen probably damaging (0.984); catalogued as COSV100442199; called by muse, mutect2
- PARD3 | c.3272G>C p.G1091A | Missense Mutation (SNP) | VAF 43/629 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as rs535507650; called by muse, mutect2
- PCDHB6 | c.470A>G p.H157R | Missense Mutation (SNP) | VAF 22/311 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV99170638; called by muse, mutect2
- PDZRN3 | c.1653C>A p.D551E | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.991); catalogued as COSV55216847; called by muse, mutect2
- PKHD1L1 | c.5173G>T p.D1725Y | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as COSV65750504; called by muse, mutect2, varscan2
- PMM2 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 62/605 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as CM137871; called by muse, mutect2, varscan2
- PPDPFL | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 18/362 reads (5%) | catalogued as COSV57461185; called by muse, mutect2
- RASAL2 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV62713370; called by muse, mutect2
- RBM33 | c.2180C>A p.S727Y | Missense Mutation (SNP) | VAF 30/746 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV56629366; called by muse, mutect2
- RCSD1 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as rs1426996848; called by muse, mutect2
- RESF1 | c.2900A>G p.H967R | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1243632179; called by muse, mutect2, varscan2
- RGPD4 | c.4952C>T p.T1651I | Missense Mutation (SNP) | VAF 92/823 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.187); catalogued as COSV61750425; called by muse, mutect2, varscan2
- RIMS2 | c.1175C>A p.S392* (on ENST00000666250 / NM_001348490.2; = p.S200* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/225 reads (11%) | catalogued as COSV51709760, COSV99192570; called by muse, mutect2, varscan2
- RYR2 | c.230C>A p.A77E | Missense Mutation (SNP) | VAF 124/784 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM056388, COSV63670229; called by muse, mutect2, varscan2
- SAMD5 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 31/345 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773161628; called by muse, mutect2
- SCTR | c.949C>A p.L317I | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV50031728; called by muse, mutect2, varscan2
- SECISBP2L | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.746); catalogued as rs753115128; called by muse, mutect2, varscan2
- SEMA5A | c.2592G>T p.R864S | Missense Mutation (SNP) | VAF 22/461 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV66790425; called by muse, mutect2
- SLC29A1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs754487166, COSV57580386; called by muse, mutect2, varscan2
- SLC6A17 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374522628; called by muse, mutect2
- SULT4A1 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50780941, COSV99970571; called by muse, mutect2
- TPSD1 | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310403043; called by muse, mutect2
- TRPS1 | c.3632A>T p.D1211V (on ENST00000220888 / NM_001330599.2; = p.D1224V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/680 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55252996; called by muse, mutect2
- TSPEAR | c.1813T>A p.S605T | Missense Mutation (SNP) | VAF 50/502 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV59982860; called by muse, mutect2
- TTLL6 | c.1798G>A p.D600N (on ENST00000393382 / NM_001130918.3; = p.D293N on NM_173623.3) | Missense Mutation (SNP) | VAF 34/506 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100938254; called by muse, mutect2
- UNC45B | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as rs543327883, COSV52092506; called by muse, mutect2
- UNC5B | c.1006C>A p.R336S | Missense Mutation (SNP) | VAF 33/432 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs1473730858, COSV100100260; called by muse, mutect2
- USP8 | c.1085T>C p.I362T | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs776889830; called by muse, mutect2, varscan2
- WDFY4 | c.2326G>A p.G776S | Missense Mutation (SNP) | VAF 38/512 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs578255781, COSV57438045; called by muse, mutect2
- ZFHX4 | c.8610C>A p.S2870R | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV50663370; called by muse, mutect2, varscan2
- ZFHX4 | c.10677C>A p.C3559* | Nonsense Mutation (SNP) | VAF 22/392 reads (6%) | catalogued as COSV51498119; called by muse, mutect2
- ZNF469 | c.11005G>C p.V3669L (on ENST00000437464; = p.V3697L on NM_001367624.2) | Missense Mutation (SNP) | VAF 20/239 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.03); catalogued as COSV71259136; called by muse, mutect2
- ZNF479 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 28/275 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV58635933; called by muse, mutect2, varscan2
- ZNF541 | c.2589G>T p.Q863H | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1288057458; called by muse, mutect2
- ABCC1 | c.3591-1G>A p.X1197_splice | Splice Site (SNP) | VAF 28/238 reads (12%) | called by muse, mutect2, varscan2
- ABCC1 | c.3591G>T p.R1197S | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABHD16A | c.131G>T p.W44L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABHD18 | c.46A>G p.T16A | Missense Mutation (SNP) | VAF 30/345 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- ACACA | c.5042A>T p.Q1681L | Missense Mutation (SNP) | VAF 49/732 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.194); called by muse, mutect2
- ACOD1 | c.907A>T p.T303S | Missense Mutation (SNP) | VAF 42/602 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.051); called by muse, mutect2
- ACOT6 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTS3 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 23/218 reads (11%) | called by muse, mutect2, varscan2
- ADGRB3 | c.212T>G p.L71R | Missense Mutation (SNP) | VAF 35/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- AGBL1 | c.2644G>A p.G882S | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALOX12 | c.1546C>A p.P516T | Missense Mutation (SNP) | VAF 23/220 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- AMPD2 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANGPTL5 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 52/396 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK1 | c.4325C>A p.S1442Y | Missense Mutation (SNP) | VAF 93/791 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ANK3 | c.12893C>T p.S4298L (on ENST00000280772 / NM_001320874.2; = p.S922L on NM_001149.3) | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.141); called by muse, mutect2
- AP3D1 | c.3356T>A p.L1119Q | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- APCDD1L | c.109T>G p.C37G | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APOBEC3B | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- ARHGAP21 | c.4906G>T p.D1636Y | Missense Mutation (SNP) | VAF 46/509 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATRN | c.1528A>T p.R510W | Missense Mutation (SNP) | VAF 16/521 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2
- BCL11B | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 15/219 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- C10orf67 | c.781A>T p.R261W | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C11orf94 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- C1orf43 | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- C2CD3 | c.3439G>A p.D1147N | Missense Mutation (SNP) | VAF 55/378 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C3orf56 | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 81/526 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- C4orf19 | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 36/302 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- C4orf54 | c.2230G>T p.G744C | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2
- C5AR1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CASQ1 | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDH18 | c.620A>T p.Y207F | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.429); called by muse, mutect2
- CDH19 | c.856G>C p.G286R | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CEP350 | c.6637A>T p.R2213W | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- CFAP54 | c.4990T>A p.F1664I | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, varscan2
- CHD3 | c.2890A>G p.M964V | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- CHRM3 | c.155C>A p.P52Q | Missense Mutation (SNP) | VAF 20/679 reads (3%) | SIFT tolerated (0.62); PolyPhen benign (0.037); called by muse, mutect2
- CLPB | c.1291G>T p.V431F | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CNTNAP5 | c.2951G>T p.C984F | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL20A1 | c.2123G>A p.G708E | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CRYL1 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CSMD2 | c.5966C>T p.P1989L | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTNND2 | c.2600C>A p.A867E | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYP19A1 | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 52/423 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- DAAM1 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 17/237 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.06); called by muse, mutect2
- DDX24 | c.241G>C p.V81L | Missense Mutation (SNP) | VAF 24/516 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- DGKE | c.294C>A p.C98* | Nonsense Mutation (SNP) | VAF 36/409 reads (9%) | called by muse, mutect2
- DLGAP2 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 35/309 reads (11%) | called by muse, mutect2, varscan2
- DMRTA2 | c.297C>A p.C99* | Nonsense Mutation (SNP) | VAF 24/344 reads (7%) | called by muse, mutect2
- DMRTA2 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DNAH17 | c.10314G>T p.W3438C | Missense Mutation (SNP) | VAF 57/526 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- DOCK7 | c.1420A>T p.K474* | Nonsense Mutation (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- DROSHA | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 32/628 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2
- DUSP22 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 27/824 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- EML2 | c.414C>G p.H138Q | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ENO2 | c.991G>T p.A331S | Missense Mutation (SNP) | VAF 46/543 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.321); called by muse, mutect2
- EPS8L1 | c.460del p.A154Lfs*46 (on ENST00000201647 / NM_133180.3; = p.A27Lfs*46 on NM_017729.3) | Frame Shift Del (DEL) | VAF 29/205 reads (14%) | called by mutect2, pindel, varscan2
- ESPNL | c.2095G>T p.A699S | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FAM163A | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 52/574 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2
- FAT1 | c.12352G>T p.G4118C | Missense Mutation (SNP) | VAF 47/415 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FATE1 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 35/410 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- FBXL6 | c.1415A>G p.H472R | Missense Mutation (SNP) | VAF 28/611 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- FRAS1 | c.434A>T p.E145V | Missense Mutation (SNP) | VAF 72/639 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- FRAT1 | c.355G>C p.G119R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FRG2 | c.421T>A p.C141S | Missense Mutation (SNP) | VAF 56/494 reads (11%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.702); called by muse, varscan2
- GBA3 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 31/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GCNA | c.449A>G p.D150G | Missense Mutation (SNP) | VAF 62/907 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- GJE1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLIPR1 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 71/491 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- GRIA3 | c.2402A>T p.D801V | Missense Mutation (SNP) | VAF 66/708 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HAO2 | c.622C>A p.L208I | Missense Mutation (SNP) | VAF 44/678 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- HDAC9 | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.478); called by muse, varscan2
- HPSE | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, mutect2
- HRH3 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- HSD11B1 | c.817dup p.R273Kfs*13 | Frame Shift Ins (INS) | VAF 30/322 reads (9%) | called by mutect2, pindel
- ICAM3 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- IER2 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.302); called by muse, mutect2
- IGKV2-30 | c.17A>T p.Q6L | Missense Mutation (SNP) | VAF 80/709 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- INSYN2B | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 15/289 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KATNIP | c.4367G>T p.R1456L | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNB2 | c.1131C>G p.I377M | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNS3 | c.398G>A p.W133* | Nonsense Mutation (SNP) | VAF 60/485 reads (12%) | called by muse, mutect2, varscan2
- KCNT2 | c.2803T>A p.L935I | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- KIAA1549 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- KLHL33 | c.386A>T p.H129L | Missense Mutation (SNP) | VAF 40/643 reads (6%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.498); called by muse, mutect2
- KRT37 | c.1327C>A p.H443N | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP6-3 | c.271T>A p.F91I | Missense Mutation (SNP) | VAF 30/414 reads (7%) | PolyPhen benign (0.01); called by muse, mutect2
- L1CAM | c.1310T>G p.M437R | Missense Mutation (SNP) | VAF 42/543 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- LGR5 | c.2086G>T p.A696S | Missense Mutation (SNP) | VAF 75/581 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LRIT3 | c.1561A>T p.K521* | Nonsense Mutation (SNP) | VAF 32/300 reads (11%) | called by muse, mutect2, varscan2
- LRP3 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LTF | c.301T>A p.Y101N | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAGED1 | c.1012T>A p.W338R | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAP2K6 | c.315G>T p.R105S | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2
- MAP3K9 | c.3024G>T p.W1008C (on ENST00000554752 / NM_001284230.1; = p.W1022C on NM_033141.4) | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); called by muse, mutect2
- MAP3K9 | c.3023G>C p.W1008S (on ENST00000554752 / NM_001284230.1; = p.W1022S on NM_033141.4) | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2
- MARCHF6 | c.1564G>T p.V522L | Missense Mutation (SNP) | VAF 19/365 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.078); called by muse, mutect2
- MMP8 | c.622+2T>A p.X208_splice | Splice Site (SNP) | VAF 19/136 reads (14%) | called by muse, mutect2, varscan2
- MRC1 | c.3213C>G p.C1071W | Missense Mutation (SNP) | VAF 71/1041 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MTOR | c.5308C>A p.P1770T | Missense Mutation (SNP) | VAF 45/536 reads (8%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYO3B | c.276C>A p.Y92* | Nonsense Mutation (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2, varscan2
- MYO6 | c.88A>T p.T30S | Missense Mutation (SNP) | VAF 60/748 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- MYOCD | c.2530G>T p.G844W | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- NATD1 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.058); called by muse, mutect2
- NBEAL1 | c.6946A>G p.I2316V | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- NIPA1 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- NKAP | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2
- NKX3-2 | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 46/405 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NOVA2 | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2
- NPAS3 | c.463T>A p.L155M (on ENST00000356141 / NM_001164749.2; = p.L123M on NM_022123.3) | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NR1H4 | c.536G>T p.C179F (on ENST00000551379 / NM_001206993.2; = p.C169F on NM_005123.4) | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NYAP2 | c.604C>G p.Q202E | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- OR13A1 | c.15G>T p.M5I | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by muse, mutect2
- OR2C3 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 44/681 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- OR2T35 | c.654C>A p.Y218* | Nonsense Mutation (SNP) | VAF 106/751 reads (14%) | called by muse, mutect2, varscan2
- OR4N2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 55/1020 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- OSER1 | c.596G>T p.C199F | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- PAX1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 28/564 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2
- PCDH11X | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 50/596 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.206); called by muse, mutect2
- PHACTR4 | c.223A>T p.R75* (on ENST00000373839 / NM_001350159.2; = p.R85* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
- PHF20L1 | c.680T>A p.V227E | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- PKD1L1 | c.2891C>T p.S964L | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKHD1 | c.9643A>G p.I3215V | Missense Mutation (SNP) | VAF 34/984 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.089); called by muse, mutect2
- POGK | c.1320G>A p.W440* | Nonsense Mutation (SNP) | VAF 28/456 reads (6%) | called by muse, mutect2
- PRAMEF19 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 82/1232 reads (7%) | called by muse, mutect2
- PRDM9 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 46/902 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2
- PRRT4 | c.2171C>T p.S724F (on ENST00000446477 / NM_001174164.1; = p.L379= on NM_001114726.3) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRZ1 | c.2949A>T p.L983F | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); called by muse, mutect2
- PURG | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB1A | c.193-1G>A p.X65_splice | Splice Site (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2, varscan2
- RADIL | c.1133G>T p.S378I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- RAPGEF2 | c.2171A>T p.Q724L | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- REM1 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 68/732 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); called by muse, mutect2
- RFXANK | c.485C>A p.S162* | Nonsense Mutation (SNP) | VAF 56/712 reads (8%) | called by muse, mutect2
- RHOJ | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RILP | c.591G>T p.Q197H | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- RNASE7 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- RNASEH2B | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RNF13 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ROBO1 | c.1544del p.A515Vfs*45 | Frame Shift Del (DEL) | VAF 15/147 reads (10%) | called by mutect2, pindel, varscan2
- RPS6KA5 | c.1298del p.G433Efs*24 | Frame Shift Del (DEL) | VAF 34/312 reads (11%) | called by mutect2, pindel, varscan2
- RYR2 | c.2576A>C p.Q859P | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- RYR3 | c.10503C>A p.H3501Q (on ENST00000389232; = p.H3502Q on NM_001036.6) | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SALL1 | c.2497C>A p.P833T | Missense Mutation (SNP) | VAF 58/562 reads (10%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SCP2 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 23/556 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.232); called by muse, mutect2
- SEL1L | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); called by muse, mutect2
- SEMA5A | c.2783G>A p.S928N | Missense Mutation (SNP) | VAF 67/594 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SEMG2 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SETBP1 | c.2321C>A p.A774E | Missense Mutation (SNP) | VAF 66/880 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); called by muse, mutect2
- SIDT1 | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 23/684 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.16); called by muse, mutect2
- SLAMF7 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 26/520 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); called by muse, mutect2
- SLC12A4 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); called by muse, mutect2
- SLC19A3 | c.910del p.D304Ifs*16 | Frame Shift Del (DEL) | VAF 33/259 reads (13%) | called by mutect2, pindel, varscan2
- SLC34A2 | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 36/396 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2
- SLC6A15 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC6A3 | c.1130T>C p.V377A | Missense Mutation (SNP) | VAF 107/982 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLCO1B3 | c.1131G>T p.L377F | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.461); called by muse, mutect2
- SLCO1C1 | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- SLITRK6 | c.1502A>T p.N501I | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ST3GAL1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 20/376 reads (5%) | PolyPhen probably damaging (0.938); called by muse, mutect2
- STIL | c.2164G>C p.A722P | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STRN3 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- TBC1D8 | c.1270C>A p.H424N | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- TBX22 | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 65/750 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.649); called by muse, mutect2
- TBXT | c.1025C>A p.T342N | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCEAL8 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.758); called by muse, mutect2
- TDP1 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 26/406 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.34); called by muse, mutect2
- TEP1 | c.1256A>T p.E419V | Missense Mutation (SNP) | VAF 41/398 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- THBS2 | c.2123C>A p.A708D | Missense Mutation (SNP) | VAF 34/399 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.755); called by muse, mutect2
- TLL1 | c.475G>T p.G159* | Nonsense Mutation (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2, varscan2
- TLL1 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- TLL2 | c.1213T>A p.W405R | Missense Mutation (SNP) | VAF 16/430 reads (4%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMC4 | c.982G>C p.V328L (on ENST00000617472 / NM_001145303.3; = p.V322L on NM_144686.4) | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2
- TMCC3 | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TMEM249 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMPRSS4 | c.1161T>A p.S387R | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TPM3 | c.164A>T p.E55V | Missense Mutation (SNP) | VAF 61/935 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- TRMT1 | c.77G>T p.W26L | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- TRRAP | c.2813C>T p.P938L | Missense Mutation (SNP) | VAF 59/450 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TSHZ3 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC29 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 90/844 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.89111T>A p.I29704K (on ENST00000591111; = p.I22280K on NM_003319.4) | Missense Mutation (SNP) | VAF 44/470 reads (9%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- TUBA3D | c.893C>A p.P298Q | Missense Mutation (SNP) | VAF 39/377 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- UNC79 | c.989T>G p.V330G (on ENST00000393151 / NM_001346218.2; = p.V153G on NM_020818.5) | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- USH2A | c.6517C>A p.L2173M | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- VSIG4 | c.980C>A p.A327D | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- VSIG4 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2
- WDHD1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- YES1 | c.1421C>A p.P474Q | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- YRDC | c.362G>T p.C121F | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- ZEB2 | c.2696C>A p.P899Q | Missense Mutation (SNP) | VAF 50/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZFHX4 | c.397T>A p.Y133N | Missense Mutation (SNP) | VAF 21/482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZFHX4 | c.8079C>A p.H2693Q | Missense Mutation (SNP) | VAF 66/518 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX4 | c.8611C>A p.P2871T | Missense Mutation (SNP) | VAF 24/209 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ZFYVE9 | c.1742C>A p.P581H | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZKSCAN7 | c.103A>T p.T35S | Missense Mutation (SNP) | VAF 114/873 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZMIZ1 | c.2397G>T p.M799I | Missense Mutation (SNP) | VAF 26/315 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.168); called by muse, mutect2
- ZNF407 | c.4060G>T p.G1354C | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF467 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 44/579 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZSCAN25 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); called by muse, mutect2
- AATK | c.138C>T p.I46= | Silent (SNP) | VAF 24/296 reads (8%) | catalogued as rs746392822; called by muse, mutect2
- ABCA9 | c.2457T>C p.L819= | Silent (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- ADAMTS3 | c.2676G>T p.P892= | Silent (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2, varscan2
- ADAMTSL3 | c.1101G>T p.V367= | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, varscan2
- ANKRD33B | c.1026G>T p.V342= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- ARSG | c.1062A>T p.P354= | Silent (SNP) | VAF 28/452 reads (6%) | called by muse, mutect2
- BRAF | c.1074G>T p.G358= | Silent (SNP) | VAF 29/289 reads (10%) | catalogued as COSV56393801; called by muse, mutect2, varscan2
- CDX4 | c.255G>C p.V85= | Silent (SNP) | VAF 32/576 reads (6%) | called by muse, mutect2
- CHRM3 | c.156A>G p.P52= | Silent (SNP) | VAF 20/668 reads (3%) | called by muse, mutect2
- CHRM3 | c.1518A>T p.P506= | Silent (SNP) | VAF 42/694 reads (6%) | called by muse, mutect2
- CIDEA | c.198C>A p.L66= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as COSV57598030; called by muse, mutect2, varscan2
- CPA6 | c.309C>T p.I103= | Silent (SNP) | VAF 28/125 reads (22%) | called by muse, mutect2, varscan2
- CTPS1 | c.846G>A p.L282= | Silent (SNP) | VAF 17/423 reads (4%) | called by muse, mutect2
- CXCR3 | c.906C>A p.V302= | Silent (SNP) | VAF 15/154 reads (10%) | called by muse, mutect2, varscan2
- DAG1 | c.222C>T p.V74= | Silent (SNP) | VAF 37/331 reads (11%) | catalogued as rs150727558; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DEGS2 | c.501C>A p.P167= | Silent (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2
- DIO3 | c.333G>T p.L111= | Silent (SNP) | VAF 17/374 reads (5%) | called by muse, mutect2
- DNAH14 | c.6822A>T p.T2274= (on ENST00000445597; = p.T2927= on NM_001367479.1) | Silent (SNP) | VAF 23/213 reads (11%) | called by muse, mutect2, varscan2
- DPF3 | c.73C>A p.R25= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as rs750004285; called by muse, mutect2
- DUOXA1 | c.313C>T p.L105= | Silent (SNP) | VAF 50/273 reads (18%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.132A>G p.P44= | Silent (SNP) | VAF 16/330 reads (5%) | called by muse, mutect2
- ERN2 | c.285C>A p.T95= | Silent (SNP) | VAF 35/391 reads (9%) | called by muse, mutect2
- FAM149A | c.642A>G p.T214= | Silent (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- FAM189A1 | c.489G>A p.Q163= | Silent (SNP) | VAF 48/300 reads (16%) | called by muse, varscan2
- FLG | c.11112T>A p.S3704= | Silent (SNP) | VAF 65/972 reads (7%) | catalogued as rs150535367; called by muse, mutect2
- FOXP2 | c.1518A>T p.P506= | Silent (SNP) | VAF 51/454 reads (11%) | called by muse, mutect2, varscan2
- FUT7 | c.405C>A p.G135= | Silent (SNP) | VAF 46/501 reads (9%) | catalogued as COSV99687712; called by muse, mutect2
- GDF10 | c.840C>T p.P280= | Silent (SNP) | VAF 11/236 reads (5%) | called by muse, mutect2
- GDF2 | c.741T>A p.G247= | Silent (SNP) | VAF 41/405 reads (10%) | called by muse, mutect2, varscan2
- GTF3C6 | c.495G>A p.E165= | Silent (SNP) | VAF 36/476 reads (8%) | called by muse, mutect2
- HCRTR2 | c.127C>T p.L43= | Silent (SNP) | VAF 68/888 reads (8%) | catalogued as COSV63795991, COSV63797908; called by muse, mutect2
- HPCAL4 | c.225C>T p.N75= | Silent (SNP) | VAF 32/532 reads (6%) | catalogued as rs201611889; called by muse, mutect2
- HTR6 | c.432G>T p.L144= | Silent (SNP) | VAF 28/464 reads (6%) | called by muse, mutect2
- IRF4 | c.798G>A p.L266= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- IRS4 | c.1794A>G p.K598= | Silent (SNP) | VAF 32/806 reads (4%) | catalogued as COSV64536329; called by muse, mutect2
- KIAA1210 | c.2289T>A p.P763= | Silent (SNP) | VAF 20/446 reads (4%) | called by muse, mutect2
- KIF13B | c.5094G>T p.P1698= | Silent (SNP) | VAF 22/688 reads (3%) | catalogued as rs1292878914; called by muse, mutect2
- KLHL17 | c.1851G>T p.V617= | Silent (SNP) | VAF 36/470 reads (8%) | called by muse, mutect2
- KRTAP27-1 | c.348C>T p.C116= | Silent (SNP) | VAF 67/645 reads (10%) | called by muse, mutect2
- LRIG3 | c.3078A>G p.P1026= | Silent (SNP) | VAF 17/497 reads (3%) | called by muse, mutect2
- LSAMP | c.450T>A p.T150= | Silent (SNP) | VAF 69/353 reads (20%) | called by muse, mutect2, varscan2
- MFN2 | c.543G>T p.V181= | Silent (SNP) | VAF 38/808 reads (5%) | called by muse, mutect2
- MICAL1 | c.399C>T p.H133= | Silent (SNP) | VAF 60/527 reads (11%) | catalogued as rs751345734; called by muse, mutect2, varscan2
- MUC12 | c.5577C>T p.S1859= (on ENST00000379442; = p.S1716= on NM_001164462.1) | Silent (SNP) | VAF 106/1692 reads (6%) | called by muse, mutect2
- MUC6 | c.618G>T p.L206= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- MYT1 | c.1239A>G p.P413= | Silent (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- NBN | c.1878C>A p.L626= | Silent (SNP) | VAF 84/513 reads (16%) | called by muse, mutect2, varscan2
- NRCAM | c.2940C>A p.G980= (on ENST00000379028 / NM_001371124.1; = p.G964= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 24/346 reads (7%) | called by muse, mutect2
- NSDHL | c.804C>A p.T268= | Silent (SNP) | VAF 20/552 reads (4%) | called by muse, mutect2
- OR2H2 | c.573C>A p.S191= | Silent (SNP) | VAF 11/264 reads (4%) | called by muse, mutect2
- OR51Q1 | c.504G>A p.L168= | Silent (SNP) | VAF 26/252 reads (10%) | called by muse, mutect2, varscan2
- OR5M8 | c.114G>A p.V38= | Silent (SNP) | VAF 24/474 reads (5%) | catalogued as COSV100510758; called by muse, mutect2
- OR6F1 | c.99G>T p.V33= | Silent (SNP) | VAF 28/404 reads (7%) | catalogued as COSV57469020; called by muse, mutect2
- PABPC5 | c.270C>A p.R90= | Silent (SNP) | VAF 33/801 reads (4%) | called by muse, mutect2
- PCDH10 | c.2316C>G p.G772= | Silent (SNP) | VAF 28/248 reads (11%) | catalogued as COSV52087280; called by muse, varscan2
- PCDH7 | c.2364C>A p.P788= | Silent (SNP) | VAF 42/527 reads (8%) | catalogued as COSV100688433; called by muse, mutect2
- PCDHB13 | c.2070G>T p.L690= | Silent (SNP) | VAF 58/714 reads (8%) | called by muse, mutect2
- PDE7B | c.267A>T p.I89= | Silent (SNP) | VAF 40/468 reads (9%) | catalogued as COSV57502165; called by muse, mutect2
- PGAM4 | c.114G>T p.A38= | Silent (SNP) | VAF 51/634 reads (8%) | catalogued as COSV100431562; called by muse, mutect2
- PGK2 | c.333A>T p.P111= | Silent (SNP) | VAF 40/488 reads (8%) | catalogued as rs1561922497; called by muse, mutect2
- PHLDB1 | c.321G>A p.G107= | Silent (SNP) | VAF 12/240 reads (5%) | catalogued as rs1555089299; called by muse, mutect2
- PLCH1 | c.1542A>T p.T514= (on ENST00000340059 / NM_001130960.2; = p.T526= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- PLVAP | c.804C>A p.I268= | Silent (SNP) | VAF 22/189 reads (12%) | called by muse, mutect2, varscan2
- RAB33A | c.441G>T p.V147= | Silent (SNP) | VAF 18/402 reads (4%) | catalogued as COSV57061273; called by muse, mutect2
- RANBP2 | c.3063A>G p.T1021= | Silent (SNP) | VAF 47/367 reads (13%) | called by muse, mutect2, varscan2
- RBP3 | c.2241T>A p.R747= | Silent (SNP) | VAF 31/629 reads (5%) | called by muse, mutect2
- RCC2 | c.696G>T p.G232= | Silent (SNP) | VAF 24/373 reads (6%) | called by muse, mutect2
- RHAG | c.1179C>T p.D393= | Silent (SNP) | VAF 22/362 reads (6%) | catalogued as rs1274681095; called by muse, mutect2
- RLIM | c.402T>C p.D134= | Silent (SNP) | VAF 30/427 reads (7%) | called by muse, mutect2
- RNF128 | c.942C>T p.C314= (on ENST00000255499 / NM_194463.2; = p.C288= on NM_024539.3) | Silent (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- RYR3 | c.9111G>A p.T3037= (on ENST00000389232; = p.T3038= on NM_001036.6) | Silent (SNP) | VAF 27/318 reads (8%) | catalogued as rs753992365, COSV66803249; called by muse, mutect2
- SAFB | c.115C>T p.L39= | Silent (SNP) | VAF 64/528 reads (12%) | catalogued as rs762619043, COSV99385865; called by muse, mutect2, varscan2
- SARDH | c.1248G>T p.L416= | Silent (SNP) | VAF 25/284 reads (9%) | called by muse, mutect2
- SEMA5A | c.963C>A p.V321= | Silent (SNP) | VAF 106/406 reads (26%) | catalogued as COSV66787763; called by muse, mutect2, varscan2
- SHARPIN | c.1083T>C p.N361= | Silent (SNP) | VAF 19/161 reads (12%) | called by muse, mutect2, varscan2
- SHOX2 | c.519G>A p.L173= (on ENST00000441443 / NM_006884.3; = p.L197= on NM_003030.4) | Silent (SNP) | VAF 99/509 reads (19%) | catalogued as COSV67464955; called by muse, mutect2, varscan2
- SLC5A7 | c.636C>A p.V212= | Silent (SNP) | VAF 43/353 reads (12%) | catalogued as COSV50905948; called by muse, mutect2, varscan2
- SRC | c.1485C>T p.H495= | Silent (SNP) | VAF 28/301 reads (9%) | catalogued as rs979391675, COSV100658247, COSV62441234; called by muse, mutect2, varscan2
- ST18 | c.777G>T p.P259= | Silent (SNP) | VAF 48/516 reads (9%) | catalogued as rs765013460; called by muse, mutect2
- SUN5 | c.774C>A p.R258= | Silent (SNP) | VAF 20/223 reads (9%) | called by muse, mutect2
- SYNE2 | c.10470A>G p.E3490= | Silent (SNP) | VAF 34/265 reads (13%) | called by muse, mutect2, varscan2
- TAP1 | c.318G>T p.L106= | Silent (SNP) | VAF 17/175 reads (10%) | called by muse, mutect2
- TBX15 | c.987C>G p.L329= (on ENST00000369429 / NM_001330677.2; = p.L223= on NM_152380.3) | Silent (SNP) | VAF 55/980 reads (6%) | called by muse, mutect2
- TCERG1L | c.93A>T p.A31= | Silent (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- TERT | c.1491G>T p.L497= | Silent (SNP) | VAF 28/642 reads (4%) | called by muse, mutect2
- TFAP2B | c.888C>T p.P296= | Silent (SNP) | VAF 66/751 reads (9%) | catalogued as rs146662170, COSV53830342, COSV53831558; called by muse, mutect2
- TH | c.1302G>T p.L434= (on ENST00000381178 / NM_199292.3; = p.L403= on NM_000360.4) | Silent (SNP) | VAF 24/536 reads (4%) | catalogued as COSV51748488; called by muse, mutect2
- TLCD4 | c.240A>T p.P80= | Silent (SNP) | VAF 18/207 reads (9%) | called by muse, mutect2
- TLR5 | c.1968C>T p.T656= | Silent (SNP) | VAF 25/220 reads (11%) | called by muse, mutect2, varscan2
- TMEM102 | c.828G>C p.A276= | Silent (SNP) | VAF 21/428 reads (5%) | called by muse, mutect2
- TRIM9 | c.285C>A p.S95= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- TRPV5 | c.417C>T p.R139= | Silent (SNP) | VAF 44/389 reads (11%) | called by muse, mutect2, varscan2
- TTLL4 | c.315A>G p.L105= | Silent (SNP) | VAF 54/365 reads (15%) | catalogued as rs920687045; called by muse, mutect2, varscan2
- UNCX | c.1032C>G p.R344= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- USH1C | c.609A>T p.G203= | Silent (SNP) | VAF 64/738 reads (9%) | called by muse, mutect2
- UTS2R | c.460C>A p.R154= | Silent (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- WNT5B | c.897G>T p.T299= | Silent (SNP) | VAF 28/350 reads (8%) | catalogued as COSV60197299; called by muse, mutect2
- ZNF696 | c.522G>T p.A174= | Silent (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- ZNF697 | c.1131C>A p.G377= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- AC068633.1 | n.179G>T | RNA (SNP) | VAF 29/265 reads (11%) | called by muse, mutect2, varscan2
- AC073648.1 | n.604C>T | RNA (SNP) | VAF 20/224 reads (9%) | catalogued as rs1394365277; called by muse, mutect2
- AL512598.2 | n.336+39212C>A | Intron (SNP) | VAF 18/405 reads (4%) | called by muse, mutect2
- AL590867.2 | n.65T>A | RNA (SNP) | VAF 52/825 reads (6%) | called by muse, mutect2
- ANKRD1 | c.*4A>T | 3'UTR (SNP) | VAF 33/419 reads (8%) | called by muse, mutect2
- AP003393.1 | n.862G>T | RNA (SNP) | VAF 94/562 reads (17%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-3455A>G | Intron (SNP) | VAF 32/384 reads (8%) | catalogued as rs1200611727; called by muse, mutect2
- C5orf38 | c.*132C>A | 3'UTR (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- CYP27A1 | c.1184+12T>A | Intron (SNP) | VAF 85/584 reads (15%) | called by muse, mutect2, varscan2
- DES | c.-23C>A | 5'UTR (SNP) | VAF 30/226 reads (13%) | called by muse, mutect2, varscan2
- EYS | c.1767-7938G>T | Intron (SNP) | VAF 54/1098 reads (5%) | called by muse, mutect2
- FDFT1 | chr8:11802421 C>T | 5'Flank (SNP) | VAF 14/193 reads (7%) | catalogued as rs887001381; called by muse, mutect2
- GALNT13 | c.1531-3706G>A | Intron (SNP) | VAF 13/124 reads (10%) | catalogued as rs1455111083; called by muse, mutect2, varscan2
- GPR61 | c.-276G>T | 5'UTR (SNP) | VAF 32/468 reads (7%) | called by muse, mutect2
- GRAMD1B | c.24-16736G>A | Intron (SNP) | VAF 55/352 reads (16%) | catalogued as rs1259485604; called by muse, mutect2, varscan2
- HINT1 | c.217-1253C>T | Intron (SNP) | VAF 11/134 reads (8%) | called by muse, mutect2
- IGBP1 | c.-13C>T | 5'UTR (SNP) | VAF 16/432 reads (4%) | catalogued as rs1330501593; called by muse, mutect2
- IRAK4 | c.162-156G>T | Intron (SNP) | VAF 28/310 reads (9%) | called by muse, mutect2
- KCND3 | chr1:111991084 G>A | 5'Flank (SNP) | VAF 13/255 reads (5%) | called by muse, mutect2
- KRT8 | c.595-19C>T | Intron (SNP) | VAF 51/360 reads (14%) | called by muse, mutect2, varscan2
- LILRB1 | chr19:54630608 C>T | 5'Flank (SNP) | VAF 19/298 reads (6%) | catalogued as rs1254407762; called by muse, mutect2
- NAA10 | c.341+19G>T | Intron (SNP) | VAF 18/348 reads (5%) | called by muse, mutect2
- NCAM1 | chr11:112961388 C>A | 5'Flank (SNP) | VAF 21/365 reads (6%) | catalogued as COSV67561750; called by muse, mutect2
- NDUFAF2 | c.127+28C>A | Intron (SNP) | VAF 20/423 reads (5%) | called by muse, mutect2
- NT5C3A | c.*151G>T | 3'UTR (SNP) | VAF 130/870 reads (15%) | catalogued as rs1274719844; called by muse, mutect2, varscan2
- PAEP | c.*11G>T | 3'UTR (SNP) | VAF 37/341 reads (11%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157404 A>T | 3'Flank (SNP) | VAF 83/1018 reads (8%) | called by muse, mutect2
- PRSS12 | c.1489+12C>A | Intron (SNP) | VAF 56/657 reads (9%) | called by muse, mutect2
- RUNX1 | c.724+64C>T | Intron (SNP) | VAF 21/185 reads (11%) | catalogued as rs1455681125; called by muse, mutect2, varscan2
- SMC4 | c.1858-15A>T | Intron (SNP) | VAF 45/277 reads (16%) | called by muse, mutect2, varscan2
- SNX22 | c.159+86C>T | Intron (SNP) | VAF 11/74 reads (15%) | catalogued as rs1436720623; called by muse, mutect2, varscan2
- SORBS2 | c.-46+1235C>A | Intron (SNP) | VAF 21/361 reads (6%) | called by muse, mutect2
- SPATA31C1 | n.794C>A | RNA (SNP) | VAF 70/782 reads (9%) | called by muse, mutect2
- SPATA31C1 | n.795C>A | RNA (SNP) | VAF 70/782 reads (9%) | catalogued as rs1354651286; called by muse, mutect2
- TMEM135 | c.*5676G>T | 3'UTR (SNP) | VAF 45/300 reads (15%) | called by muse, mutect2, varscan2
- TUBB7P | n.479C>A | RNA (SNP) | VAF 91/876 reads (10%) | called by muse, varscan2
- ULBP2 | c.*50T>A | 3'UTR (SNP) | VAF 16/362 reads (4%) | called by muse, mutect2
- XIAP | c.*5940C>T | 3'UTR (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- XIST | n.9536G>T | RNA (SNP) | VAF 9/114 reads (8%) | catalogued as rs1213988449; called by muse, mutect2
- ZEB1 | c.58+43640C>A | Intron (SNP) | VAF 58/692 reads (8%) | called by muse, mutect2
- ZFPM2 | n.330G>T | RNA (SNP) | VAF 12/94 reads (13%) | called by muse, varscan2
- ZNF467 | chr7:149777647 G>C | 5'Flank (SNP) | VAF 26/276 reads (9%) | called by muse, mutect2
